CCDI case PBBVKI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/54282896-974f-4b1c-8cab-ba6f4c63b6d2

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Malignant tumor, spindle cell type: ICD-O-3 morphology code: 8004/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.7 years (4,269 days).

Biospecimens (3 samples)
- Sample 0DIMVO: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DIMWJ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DIMWW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
